Somatic mutation profile of tumor specimen 0DPUTM from CCDI case PBCEHB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.7 years (5,004 days).
Specimen 0DPUTM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1752bd34-f6a2-48bd-a926-32647db4b42d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPUTI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5e38ad3-83cd-45a1-927d-ef2141323ea7

The open-access MAF lists 31 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Intron 5, 3'UTR 2, 5'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CALHM3 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 97/200 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324324553; called by muse, mutect2, varscan2
- CASZ1 | c.4448G>A p.R1483H | Missense Mutation (SNP) | VAF 106/453 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65458636; called by muse, mutect2, varscan2
- ERVV-1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 57/487 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as rs1165654836; called by muse, mutect2, varscan2
- GRIN1 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 159/645 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.551); catalogued as rs140422926; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MDM4 | c.871A>G p.S291G | Missense Mutation (SNP) | VAF 202/764 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as rs28495289; called by muse, mutect2, varscan2
- PCDHA3 | c.848C>T p.T283M | Missense Mutation (SNP) | VAF 160/616 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.277); catalogued as rs781990436, COSV65365409, COSV65367472; called by muse, mutect2, varscan2
- SLC11A1 | c.1460A>G p.Y487C | Missense Mutation (SNP) | VAF 32/588 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs139317500, COSV51919483; called by muse, mutect2
- SPTBN1 | c.2023C>T p.R675C | Missense Mutation (SNP) | VAF 183/316 reads (58%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.93); catalogued as rs1217173204; called by muse, mutect2, varscan2
- TNFRSF11A | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 56/1076 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs537966416, COSV54021966; called by muse, mutect2
- ABHD17B | c.765G>T p.E255D | Missense Mutation (SNP) | VAF 236/1000 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- ASPM | c.2072A>T p.Y691F | Missense Mutation (SNP) | VAF 26/786 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); called by muse, mutect2
- CDR2 | c.1306A>T p.T436S | Missense Mutation (SNP) | VAF 42/558 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2
- COL4A4 | c.2126C>A p.P709H | Missense Mutation (SNP) | VAF 177/503 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- OR2G3 | c.638T>A p.L213H | Missense Mutation (SNP) | VAF 102/498 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by mutect2, varscan2
- PKDREJ | c.4880C>A p.P1627Q | Missense Mutation (SNP) | VAF 105/799 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- SMARCA5 | c.753G>A p.W251* | Nonsense Mutation (SNP) | VAF 211/832 reads (25%) | called by muse, mutect2, varscan2
- BMP4 | c.951C>T p.F317= | Silent (SNP) | VAF 188/344 reads (55%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.504T>C p.V168= | Silent (SNP) | VAF 15/230 reads (7%) | called by muse, mutect2
- MFAP3L | c.93G>C p.V31= | Silent (SNP) | VAF 185/626 reads (30%) | called by muse, mutect2, varscan2
- TRIM38 | c.1314G>A p.P438= | Silent (SNP) | VAF 31/678 reads (5%) | catalogued as rs1273319550, COSV62641977; called by muse, mutect2
- TRPC7 | c.1141C>T p.L381= | Silent (SNP) | VAF 87/376 reads (23%) | catalogued as COSV100726098; called by muse, mutect2, varscan2
- ZFAT | c.2688T>C p.L896= | Silent (SNP) | VAF 44/462 reads (10%) | called by muse, mutect2
- AL157944.1 | n.887+67863C>T | Intron (SNP) | VAF 48/91 reads (53%) | called by muse, mutect2
- BRD8 | c.2250-27C>G | Intron (SNP) | VAF 60/159 reads (38%) | catalogued as rs969456601; called by muse, mutect2, varscan2
- DNM1 | c.-61G>A | 5'UTR (SNP) | VAF 11/63 reads (17%) | called by muse, varscan2
- FARP1 | c.-12G>C | 5'UTR (SNP) | VAF 14/338 reads (4%) | catalogued as COSV60341711; called by muse, mutect2
- MLIP | c.613-11496C>A | Intron (SNP) | VAF 140/578 reads (24%) | called by muse, mutect2, varscan2
- RNF31 | c.2131-42T>C | Intron (SNP) | VAF 14/33 reads (42%) | catalogued as rs757086038; called by muse, mutect2, varscan2
- ROMO1 | c.*69del | 3'UTR (DEL) | VAF 19/107 reads (18%) | called by mutect2, varscan2
- TGFB1I1 | c.129+31C>T | Intron (SNP) | VAF 49/269 reads (18%) | called by muse, mutect2, varscan2
- UVSSA | c.*9647C>T | 3'UTR (SNP) | VAF 84/278 reads (30%) | called by mutect2, varscan2
